Somatic mutation profile of tumor specimen TCGA-D5-6929-01A (aliquot TCGA-D5-6929-01A-31D-1924-10) from TCGA case TCGA-D5-6929, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 49.1 years (17,919 days).
Specimen TCGA-D5-6929-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 815e22e7-559a-4897-bd25-58932f362062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6929-10A (Blood Derived Normal), aliquot TCGA-D5-6929-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73739c90-9d94-4f2d-a366-83c1dcce417e

The open-access MAF lists 137 somatic variants for this specimen: 106 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 29, Nonsense Mutation 8, Frame Shift Del 5, Frame Shift Ins 3, In Frame Del 2, Splice Site 2, Intron 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121964980, CM051081; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs138685512, COSV51903170; called by muse, mutect2, varscan2
- ACTN1 | c.2342A>G p.D781G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51992840; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54451102, COSV54471087; called by muse, mutect2, varscan2
- AKAP11 | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV50297427; called by muse, mutect2, varscan2
- AKAP6 | c.4109G>A p.G1370E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV55215977; called by muse, mutect2, varscan2
- ARC | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV63078763; called by muse, mutect2, varscan2
- BCAS3 | c.1729G>A p.G577R (on ENST00000390652 / NM_001353144.2; = p.G562R on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs772813265, COSV66775053; called by muse, mutect2, varscan2
- BRCA2 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV101203927; called by muse, mutect2, varscan2
- CACNB3 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56398735; called by muse, mutect2, varscan2
- CHRNB1 | c.1021_1022insT p.Q341Lfs*49 | Frame Shift Ins (INS) | VAF 21/106 reads (20%) | catalogued as COSV60140622; called by mutect2, pindel, varscan2
- CNTNAP4 | c.1819T>C p.Y607H | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1483911404, COSV56683559; called by muse, mutect2
- COL19A1 | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59575004; called by muse, mutect2, varscan2
- COL6A3 | c.6148G>A p.G2050R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559229255, COSV55092386; called by muse, mutect2, varscan2
- CRNKL1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs1249662730, COSV55619221; called by muse, mutect2, varscan2
- CSMD3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 144/400 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs756292276, COSV52240381; called by muse, mutect2, varscan2
- CTNNA3 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV57719732; called by muse, mutect2, varscan2
- DECR1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55168918; called by muse, mutect2, varscan2
- DIAPH3 | c.2659G>A p.V887I (on ENST00000400324 / NM_001042517.2; = p.V624I on NM_030932.3) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV57371533; called by muse, mutect2, varscan2
- DIS3L2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as rs937249326, COSV56055551; ClinVar: uncertain significance; called by muse, mutect2
- DMBT1 | c.7441C>T p.R2481C (on ENST00000338354 / NM_001377530.1; = p.R1724C on NM_004406.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1034308642, COSV57533768; called by muse, mutect2, varscan2
- DOCK2 | c.2933A>T p.D978V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56962064; called by muse, mutect2, varscan2
- ELOVL2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867506828, COSV61155340; called by muse, mutect2
- ENPP4 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.054); catalogued as COSV100320233; called by muse, mutect2
- ENTPD4 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs372620648; called by muse, mutect2, varscan2
- EPRS1 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65099362; called by muse, mutect2, varscan2
- FNDC8 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs537116877, COSV50101610; called by muse, mutect2, varscan2
- GPBP1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV53312006; called by muse, mutect2, varscan2
- GPR146 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145638311; called by muse, mutect2, varscan2
- HCAR3 | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as COSV100811452; called by muse, mutect2, varscan2
- IDO2 | c.475C>T p.P159S (on ENST00000389060; = p.P172S on NM_194294.2) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752076671, COSV58425989; called by muse, mutect2, varscan2
- IGF2BP3 | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV51685855; called by muse, mutect2, varscan2
- IGSF9B | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100318481, COSV58068488, COSV58072530; called by muse, mutect2
- INSRR | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.855); catalogued as COSV63873931; called by muse, mutect2, varscan2
- IPO5 | c.1591T>A p.Y531N | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55155098; called by muse, mutect2, varscan2
- IQCN | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs139542395, COSV66574724; called by muse, mutect2, varscan2
- ITGB3 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101457649, COSV71384183; called by muse, mutect2
- JAG2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769513887, COSV59309716; called by muse, varscan2
- KIF4B | c.2420G>A p.G807D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1312645745, COSV70529693; called by muse, mutect2, varscan2
- KLHL14 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.926); catalogued as COSV63832971; called by muse, mutect2, varscan2
- KMT2C | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145833795, COSV51435255; called by muse, mutect2, varscan2
- KRT17 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100245040; called by muse, mutect2, varscan2
- KRT5 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200156424, COSV52861060; called by muse, mutect2, varscan2
- KRTAP1-5 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV62624119, COSV62624318; called by muse, mutect2, varscan2
- LCT | c.4343G>A p.R1448H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51544276; called by muse, mutect2, varscan2
- LRPPRC | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53239120; called by muse, mutect2, varscan2
- MAP3K3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62280866; called by muse, mutect2, varscan2
- MAP4K1 | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as COSV101204137; called by muse, mutect2
- MROH5 | c.3629C>G p.A1210G | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100267080; called by muse, mutect2
- MTF2 | c.1103C>G p.T368R | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.543); catalogued as COSV64770711; called by muse, mutect2, varscan2
- NAV3 | c.5689T>G p.S1897A (on ENST00000397909 / NM_001024383.2; = p.S1875A on NM_014903.6) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV57061938, COSV57079842; called by muse, mutect2, varscan2
- NAV3 | c.5693-2A>G p.X1898_splice (on ENST00000397909 / NM_001024383.2; = p.X1876_splice on NM_014903.6) | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as COSV57084157; called by muse, mutect2, varscan2
- NEK4 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs750998173, COSV51780755; called by muse, mutect2, varscan2
- NLRC5 | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV52656530; called by muse, mutect2, varscan2
- NPAT | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 51/130 reads (39%) | catalogued as COSV53718412; called by muse, mutect2, varscan2
- NUDCD1 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454124661, COSV53454715; called by muse, mutect2
- OR2W1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65851649, COSV65851728; called by muse, mutect2
- OR51A7 | c.939A>C p.*313Yext*? | Nonstop Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV63788473; called by muse, mutect2, varscan2
- OR5AC2 | c.172C>G p.H58D | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62279253, COSV62279601; called by muse, mutect2, varscan2
- OR5R1 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.447); catalogued as COSV56572542; called by muse, mutect2, varscan2
- PAPPA2 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62779438; called by muse, mutect2, varscan2
- PDPR | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs540468792, COSV55352841; called by muse, mutect2, varscan2
- PGS1 | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.631); catalogued as COSV53145764, COSV99428529; called by muse, varscan2
- PKHD1L1 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65744434; called by muse, mutect2, varscan2
- PTGFRN | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV67798712; called by muse, mutect2, varscan2
- RABGGTB | c.910_912del p.E304del | In Frame Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs773036418; called by pindel, varscan2
- RADX | c.2374A>G p.S792G | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.508); catalogued as COSV65318979; called by muse, mutect2, varscan2
- RGL3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs778182703, COSV62698129; called by muse, mutect2, varscan2
- RHOXF1 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99483742; called by muse, mutect2
- RNF41 | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV61504499; called by muse, mutect2, varscan2
- S100A9 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142015410; called by muse, mutect2, varscan2
- SERTAD4 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200231133, COSV65398758, COSV65399765; called by muse, mutect2, varscan2
- SIDT2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54057462; called by muse, mutect2, varscan2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 35/192 reads (18%) | catalogued as rs771462597; called by mutect2, varscan2
- SLC4A1 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 19/173 reads (11%) | catalogued as CM1212123, COSV52260538; called by muse, mutect2, varscan2
- SLC9A5 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.191); catalogued as COSV55362442; called by muse, mutect2, varscan2
- SPATC1 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV104426700, COSV66299048; called by muse, mutect2
- ST6GAL2 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | PolyPhen probably damaging (0.949); catalogued as COSV62416942; called by muse, mutect2, varscan2
- SYNE1 | c.11936G>T p.R3979L (on ENST00000367255 / NM_182961.4; = p.R3908L on NM_033071.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV99553463; called by muse, mutect2, varscan2
- TAMALIN | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV53336846; called by muse, mutect2
- TAMALIN | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53336268, COSV53336861; called by muse, mutect2, varscan2
- TAPT1 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV58824501; called by muse, mutect2
- TEP1 | c.7515G>C p.W2505C | Missense Mutation (SNP) | VAF 170/703 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52993699; called by muse, mutect2, varscan2
- TNS3 | c.4179T>A p.D1393E | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as COSV60792129; called by muse, mutect2, varscan2
- TREM2 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV58294762; called by muse, mutect2, varscan2
- TTC27 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV58652875; called by muse, mutect2, varscan2
- VMP1 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as COSV51868187; called by muse, mutect2, varscan2
- ZIK1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 95/225 reads (42%) | catalogued as COSV56737359, COSV56738148; called by muse, mutect2, varscan2
- ZNF24 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV54348048; called by muse, varscan2
- ZNF24 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as COSV99734177; called by muse, varscan2
- ZNF276 | c.398C>T p.P133L (on ENST00000443381 / NM_001113525.2; = p.P58L on NM_152287.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57067272, COSV57068860; called by muse, mutect2, varscan2
- ZNF391 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV99772404; called by muse, mutect2, varscan2
- ZNF518B | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV58722951; called by muse, mutect2, varscan2
- ZNF622 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs771709029, COSV58074281; called by muse, mutect2, varscan2
- ACACA | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- APC | c.2226del p.M743Cfs*18 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- HNRNPDL | c.759del p.F253Lfs*35 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- MARCKSL1 | c.246del p.K83Rfs*18 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- PFKFB1 | c.630A>C p.E210D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | PolyPhen benign (0); called by muse, mutect2
- PON2 | c.930_933del p.S311Rfs*5 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- SOX9 | c.71_72dup p.T25Pfs*37 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- TBC1D14 | c.1556del p.L519* | Frame Shift Del (DEL) | VAF 29/154 reads (19%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.740_745del p.M247_L248del | In Frame Del (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- ZNF620 | c.24+6_24+9del p.X8_splice | Splice Site (DEL) | VAF 5/29 reads (17%) | called by pindel, varscan2
- ACSM2B | c.1107T>C p.T369= | Silent (SNP) | VAF 20/440 reads (5%) | catalogued as COSV61657267, COSV61658124; called by muse, mutect2
- ARHGEF6 | c.2052C>A p.S684= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV99166349; called by muse, mutect2
- ATP5PD | c.99C>T p.S33= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV56902556; called by muse, mutect2, varscan2
- BCL11B | c.2391G>A p.T797= (on ENST00000357195 / NM_001282237.2; = p.T726= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV61735975; called by muse, mutect2
- ESRP2 | c.2142T>G p.P714= (on ENST00000565858 / NM_001365264.1; = p.P704= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV52173851; called by muse, mutect2, varscan2
- ETV6 | c.1107G>A p.R369= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99844576; called by muse, mutect2
- FBXO43 | c.732A>G p.L244= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV71054217; called by muse, mutect2, varscan2
- GPR152 | c.351C>A p.S117= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV56886782; called by muse, mutect2, varscan2
- GRPEL2 | c.108C>A p.T36= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV61387676; called by muse, mutect2, varscan2
- GTF3C5 | c.15G>A p.A5= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV59600237; called by muse, mutect2, varscan2
- IGHG1 | c.570C>T p.T190= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs372846612; called by muse, mutect2, varscan2
- KRT81 | c.1494C>T p.C498= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs200814913, COSV59809194; called by muse, mutect2, varscan2
- MRC1 | c.144T>A p.A48= | Silent (SNP) | VAF 74/321 reads (23%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3573G>A p.S1191= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs371488508, COSV99919970; ClinVar: likely benign; called by muse, mutect2
- NEDD4L | c.2121G>A p.L707= (on ENST00000400345 / NM_001144967.3; = p.L687= on NM_015277.6) | Silent (SNP) | VAF 68/202 reads (34%) | catalogued as COSV56845942; called by muse, mutect2, varscan2
- NLGN4X | c.543C>A p.T181= | Silent (SNP) | VAF 43/208 reads (21%) | catalogued as COSV99319871; called by muse, mutect2, varscan2
- PCDHA2 | c.2199G>A p.A733= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV65367530; called by muse, mutect2, varscan2
- PCDHGA6 | c.2202C>T p.S734= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs1303749719, COSV99530694; called by muse, mutect2, varscan2
- PHLDB1 | c.1413G>A p.P471= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs368906730; called by muse, mutect2, varscan2
- PTCHD4 | c.1599C>T p.S533= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs745532050, COSV59786243; called by muse, mutect2, varscan2
- SEMA6B | c.1245G>A p.A415= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs144907430, COSV100015113; called by muse, mutect2, varscan2
- SLC36A2 | c.654C>T p.I218= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58863577; called by muse, mutect2, varscan2
- SORCS1 | c.1851G>A p.G617= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV53871358; called by muse, mutect2, varscan2
- SORL1 | c.2277G>A p.E759= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV52755622; called by muse, mutect2, varscan2
- TRPM8 | c.909T>C p.C303= | Silent (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- TTN | c.36507G>T p.V12169= (on ENST00000591111; = p.V4745= on NM_003319.4) | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV60106770; called by muse, mutect2, varscan2
- WAPL | c.1935T>C p.V645= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV53935841; called by muse, mutect2, varscan2
- ZIK1 | c.135T>C p.D45= | Silent (SNP) | VAF 93/224 reads (42%) | catalogued as COSV56737349; called by muse, mutect2, varscan2
- ZNF75A | c.324G>A p.Q108= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV73039628; called by muse, mutect2, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 26/117 reads (22%) | catalogued as rs781996539; called by mutect2, pindel, varscan2
- WASF4P | n.589A>T | RNA (SNP) | VAF 85/420 reads (20%) | called by muse, mutect2, varscan2
